Somatic mutation profile of tumor specimen TCGA-TS-A8AS-01A (aliquot TCGA-TS-A8AS-01A-21D-A39R-32) from TCGA case TCGA-TS-A8AS, project TCGA-MESO (Mesothelioma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Epithelioid mesothelioma, malignant; Tissue or organ of origin: Pleura, NOS; AJCC pathologic stage: Stage IA; Age at diagnosis: 77.4 years (28,273 days).
Specimen TCGA-TS-A8AS-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3b3a2439-9392-40e4-86b9-23dd7d1b207d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-TS-A8AS-10A (Blood Derived Normal), aliquot TCGA-TS-A8AS-10A-01D-A39U-32; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/10032923-555e-4a70-912d-fcbf2d089860

The open-access MAF lists 18 somatic variants for this specimen: 14 protein-altering or splice-affecting, 3 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 12, Silent 3, Intron 1, Splice Site 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRTAP6-3 | c.290G>A p.R97K | Missense Mutation (SNP) | VAF 18/174 reads (10%) | PolyPhen benign (0.029); catalogued as rs113124062; called by muse, mutect2, varscan2
- LRFN1 | c.731C>T p.P244L | Missense Mutation (SNP) | VAF 27/195 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.011); catalogued as rs367765045, COSV50448209; called by muse, mutect2, varscan2
- VEPH1 | c.173T>C p.V58A | Missense Mutation (SNP) | VAF 20/87 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1447132648; called by muse, mutect2, varscan2
- BAP1 | c.652_659+24del p.X218_splice | Splice Site (DEL) | VAF 14/74 reads (19%) | called by mutect2, pindel
- C16orf71 | c.683G>T p.G228V | Missense Mutation (SNP) | VAF 16/100 reads (16%) | SIFT tolerated (0.07); PolyPhen benign (0.154); called by muse, mutect2, varscan2
- CNNM1 | c.1860A>C p.E620D | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.684); called by muse, mutect2
- CPSF1 | c.2728A>T p.K910* | Nonsense Mutation (SNP) | VAF 31/277 reads (11%) | called by muse, mutect2, varscan2
- NEPRO | c.868A>G p.N290D | Missense Mutation (SNP) | VAF 4/23 reads (17%) | SIFT tolerated (0.33); PolyPhen benign (0.085); called by muse, mutect2, varscan2
- PDIA5 | c.440A>G p.D147G | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.374); called by muse, mutect2, varscan2
- RAD23B | c.43A>G p.I15V | Missense Mutation (SNP) | VAF 7/87 reads (8%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.768); called by muse, mutect2
- RNF213 | c.9091G>C p.G3031R | Missense Mutation (SNP) | VAF 7/83 reads (8%) | SIFT tolerated (0.14); PolyPhen benign (0.222); called by muse, mutect2
- SNX32 | c.617T>C p.F206S | Missense Mutation (SNP) | VAF 24/324 reads (7%) | SIFT deleterious (0.05); PolyPhen benign (0.047); called by muse, mutect2
- TENT5C | c.824T>A p.F275Y | Missense Mutation (SNP) | VAF 13/107 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- WHRN | c.265C>T p.R89C | Missense Mutation (SNP) | VAF 18/146 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); called by muse, mutect2, varscan2
- ADRA1D | c.1107G>A p.P369= | Silent (SNP) | VAF 22/143 reads (15%) | catalogued as rs1270979432, COSV65241321; called by muse, mutect2, varscan2
- CSPG5 | c.1677C>T p.N559= (on ENST00000383738 / NM_001206943.2; = p.N532= on NM_006574.4) | Silent (SNP) | VAF 14/88 reads (16%) | called by muse, mutect2, varscan2
- KREMEN1 | c.1215A>G p.T405= (on ENST00000407188; = p.T407= on NM_032045.5) | Silent (SNP) | VAF 10/104 reads (10%) | catalogued as rs762203084; called by muse, mutect2
- PGM1 | c.247-5937G>C | Intron (SNP) | VAF 10/83 reads (12%) | catalogued as rs1557709590; called by muse, mutect2, varscan2
